Somatic mutation profile of tumor specimen TCGA-55-7728-01A (aliquot TCGA-55-7728-01A-11D-2184-08) from TCGA case TCGA-55-7728, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.4 years (23,505 days).
Specimen TCGA-55-7728-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fc1ff95-0466-49d8-be2e-ea95bfd8b375.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7728-10A (Blood Derived Normal), aliquot TCGA-55-7728-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b5ce87e-670e-465e-a886-0d950281e275

The open-access MAF lists 96 somatic variants for this specimen: 73 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 20, Nonsense Mutation 5, 3'UTR 1, Translation Start Site 1, RNA 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | hotspot (GDC flag); catalogued as rs865931787, COSV66559513; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 27/62 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACKR4 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV51443501; called by mutect2, varscan2
- ACTR3 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV54304010; called by muse, mutect2, varscan2
- ADAM18 | c.281A>T p.Y94F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55854790; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58446563; called by muse, mutect2, varscan2
- ADNP2 | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV51542235; called by muse, mutect2, varscan2
- ALK | c.2623G>A p.G875R | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148001139, COSV66571728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP12 | c.1988A>T p.Q663L | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV60966215; called by muse, mutect2, varscan2
- ATP11B | c.1570T>C p.Y524H | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60033187; called by muse, mutect2
- AXL | c.1333G>T p.A445S (on ENST00000301178 / NM_021913.5; = p.A436S on NM_001699.6) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV56574672; called by muse, varscan2
- BCHE | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV52262217; called by muse, mutect2
- C2orf78 | c.1833A>T p.Q611H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV68519284; called by muse, mutect2, varscan2
- CCDC127 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as COSV57258030; called by muse, mutect2, varscan2
- CCDC150 | c.3266C>T p.P1089L | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55876898; called by muse, mutect2, varscan2
- CHGB | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs143107119; called by muse, mutect2, varscan2
- CLCA1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs371482526; called by muse, mutect2
- CUL9 | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.715); catalogued as COSV52734390; called by muse, mutect2, varscan2
- DISP1 | c.3566A>C p.H1189P | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52664769; called by muse, mutect2, varscan2
- DPP3 | c.754G>C p.A252P | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV64758038; called by muse, mutect2, varscan2
- ENPP1 | c.2665A>G p.I889V | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1166287765, COSV62936123; called by muse, mutect2
- ERBB4 | c.2523T>A p.H841Q | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61521241; called by muse, mutect2
- FAT3 | c.7459C>T p.L2487F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.793); catalogued as COSV53090006; called by muse, mutect2, varscan2
- FBXO40 | c.1383C>A p.S461R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100573263, COSV57527397; called by muse, mutect2, varscan2
- FDX2 | c.511A>T p.K171* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as COSV58533895; called by muse, mutect2
- FLG | c.11807A>T p.Q3936L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV64248562; called by muse, mutect2, varscan2
- GOLGA3 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV52642796, COSV52644949; called by muse, mutect2, varscan2
- GPR50 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs200441669, COSV54440276; called by muse, mutect2, varscan2
- GRIK5 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs782740109, COSV53485379; called by muse, mutect2, varscan2
- H2AC1 | c.209C>A p.A70E | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV51237448, COSV51237689; called by muse, mutect2, varscan2
- HELZ2 | c.7414G>T p.V2472L (on ENST00000467148 / NM_001037335.2; = p.V1903L on NM_033405.3) | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as rs748230640, COSV64443501; called by muse, mutect2, varscan2
- HNRNPM | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57693306, COSV57694595; called by muse, mutect2, varscan2
- HSPG2 | c.6724G>T p.G2242* | Nonsense Mutation (SNP) | VAF 31/225 reads (14%) | catalogued as COSV65977039; called by muse, mutect2, varscan2
- IMPG1 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV64061595; called by muse, mutect2, varscan2
- ITGAL | c.3451G>C p.D1151H | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV63322401, COSV63324272; called by muse, mutect2, varscan2
- KCNH3 | c.3131C>A p.P1044H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.358); catalogued as COSV57792823; called by muse, mutect2, varscan2
- KLHL11 | c.359A>T p.E120V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV59863080; called by mutect2, varscan2
- KMO | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV63810578; called by muse, mutect2, varscan2
- KMT2D | c.6826C>T p.P2276S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs368486128; called by muse, mutect2, varscan2
- LRP6 | c.4255G>T p.A1419S | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53793878; called by muse, mutect2, varscan2
- LTBP2 | c.3932C>G p.T1311S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.846); catalogued as rs1423824699, COSV56213902; called by muse, mutect2, varscan2
- NOX3 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99343468; called by muse, mutect2, varscan2
- NPAP1 | c.3353C>A p.A1118D | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as COSV61510840; called by muse, mutect2, varscan2
- OR4K1 | c.474C>A p.S158R | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53458621, COSV53462414; called by muse, mutect2, varscan2
- OTOF | c.4963C>A p.Q1655K (on ENST00000272371 / NM_194248.3; = p.Q888K on NM_004802.4) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV55518511; called by muse, mutect2, varscan2
- PAQR5 | c.907A>T p.I303F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61819149; called by muse, mutect2, varscan2
- PCDHB12 | c.1642C>A p.R548S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV53394584, COSV53400433; called by muse, mutect2, varscan2
- PFKFB1 | c.215C>A p.P72Q | Missense Mutation (SNP) | VAF 69/357 reads (19%) | PolyPhen benign (0.039); catalogued as COSV66629400; called by muse, mutect2, varscan2
- PKHD1L1 | c.9806C>A p.P3269H | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV65743388, COSV65752394; called by muse, mutect2, varscan2
- PLA2G1B | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV57679565, COSV57680250; called by muse, mutect2, varscan2
- PLEC | c.13310G>A p.R4437Q (on ENST00000322810 / NM_201380.4; = p.R4327Q on NM_000445.5) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs371875530; called by muse, mutect2
- POU3F3 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1307492164, COSV63722429; called by muse, mutect2, varscan2
- PPEF1 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV62996666; called by muse, mutect2, varscan2
- PPP1R16B | c.1497C>G p.S499R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as COSV55384397; called by muse, mutect2, varscan2
- PRKCQ | c.498C>G p.F166L | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54118783, COSV54118958; called by muse, mutect2, varscan2
- PRRG2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as rs778423334, COSV55871673; called by muse, mutect2, varscan2
- RFFL | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52074189; called by muse, mutect2, varscan2
- ROBO2 | c.2864C>A p.P955Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV59936874; called by muse, mutect2, varscan2
- SEPTIN12 | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51619002; called by muse, mutect2, varscan2
- SLC11A1 | c.1460A>G p.Y487C | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs139317500, COSV51919483; called by muse, mutect2, varscan2
- SLC12A6 | c.2808G>T p.W936C (on ENST00000354181 / NM_001365088.1; = p.W885C on NM_005135.2) | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51631496; called by muse, mutect2, varscan2
- SNCAIP | c.1805C>A p.S602* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as COSV54420924; called by muse, mutect2, varscan2
- SYCP2 | c.4352G>T p.S1451I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100698364; called by muse, mutect2, varscan2
- TIAM2 | c.1477C>A p.L493M | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV59703813; called by muse, mutect2, varscan2
- TMEM89 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56575393; called by muse, mutect2, varscan2
- TSPOAP1 | c.3626G>C p.R1209P | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs760194696, COSV52117358; called by muse, mutect2, varscan2
- TTC39B | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52616555; called by muse, mutect2, varscan2
- TWF1 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100286153; called by muse, mutect2, varscan2
- WDFY3 | c.960G>T p.L320F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV55713316; called by muse, mutect2, varscan2
- ZNF404 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60988845; called by muse, mutect2, varscan2
- ZNF677 | c.1424G>A p.W475* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV61721476; called by muse, mutect2, varscan2
- ZNF699 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV58026978; called by muse, mutect2, varscan2
- FDXR | c.295_297delinsT p.T99Cfs*47 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by pindel, varscan2*
- ANO1 | c.177G>T p.R59= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100304265; called by muse, mutect2, varscan2
- CACNG1 | c.78C>A p.A26= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV56827826; called by muse, mutect2, varscan2
- CNDP2 | c.381G>A p.G127= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV60841561; called by muse, mutect2
- COQ7 | c.525G>A p.R175= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100430581, COSV58982590; called by muse, mutect2, varscan2
- CTTN | c.1359C>T p.Y453= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1295217725, COSV57236068; called by muse, mutect2, varscan2
- FAM3D | c.48A>T p.I16= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV62559533; called by muse, mutect2, varscan2
- GATA6 | c.186G>T p.T62= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV52527848; called by muse, mutect2, varscan2
- ITPR1 | c.2154G>A p.Q718= (on ENST00000354582; = p.Q703= on NM_002222.7) | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1433639929, COSV57002546; called by mutect2, varscan2
- KCNA3 | c.810G>T p.S270= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs1318178157, COSV63902552; called by muse, mutect2, varscan2
- NHSL2 | c.2019G>A p.L673= (on ENST00000510661; = p.L1039= on NM_001013627.2) | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs147793067, COSV65454914; called by muse, mutect2, varscan2
- NOX3 | c.78G>T p.L26= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs1352845888, COSV99343459; called by muse, mutect2, varscan2
- NRXN3 | c.2145C>A p.S715= (on ENST00000335750 / NM_001330195.2; = p.S342= on NM_004796.6) | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV59728645, COSV59805023; called by muse, mutect2, varscan2
- PAK5 | c.1302G>A p.A434= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs200630536, COSV62037468; called by muse, mutect2, varscan2
- PARP4 | c.3093C>T p.S1031= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV67964110; called by muse, mutect2, varscan2
- PLXNA3 | c.3678G>T p.A1226= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV63755608; called by muse, mutect2, varscan2
- SATL1 | c.651A>T p.S217= (on ENST00000395409; = p.S404= on NM_001012980.2) | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as COSV60578252; called by muse, mutect2, varscan2
- SCAP | c.156A>T p.T52= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV55565764; called by muse, mutect2, varscan2
- SRD5A2 | c.24C>T p.S8= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV51873600; called by muse, mutect2, varscan2
- TUBB6 | c.729G>A p.P243= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as rs756946980, COSV52317284; called by muse, mutect2, varscan2
- UNC79 | c.6855T>A p.V2285= (on ENST00000393151 / NM_001346218.2; = p.V2108= on NM_020818.5) | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV56409201; called by muse, varscan2
- DLG2 | c.205-65785G>A | Intron (SNP) | VAF 53/318 reads (17%) | catalogued as rs996545665, COSV99717858; called by muse, mutect2, varscan2
- LYPD6 | c.*2G>T | 3'UTR (SNP) | VAF 20/143 reads (14%) | catalogued as COSV100493651; called by muse, mutect2, varscan2
- TCP10L3 | n.471G>T | RNA (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100833164; called by mutect2, varscan2
